Somatic mutation profile of tumor specimen TCGA-GU-A764-01A (aliquot TCGA-GU-A764-01A-11D-A34U-08) from TCGA case TCGA-GU-A764, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 66.6 years (24,343 days).
Specimen TCGA-GU-A764-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da88d683-2b8e-4062-8b66-67ece1ebfcfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GU-A764-10B (Blood Derived Normal), aliquot TCGA-GU-A764-10B-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae9b394e-a06a-4f48-a3f0-f46a1844fc76

The open-access MAF lists 121 somatic variants for this specimen: 91 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 28, Nonsense Mutation 7, Frame Shift Del 2, In Frame Del 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 35/240 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50461395, COSV50462411; called by muse, mutect2, varscan2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACOT12 | c.1309C>T p.H437Y | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs372830969; called by muse, mutect2, varscan2
- ACOT8 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99467300; called by muse, mutect2, varscan2
- ACOX3 | c.258C>G p.F86L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV62711095, COSV62711369; called by muse, mutect2, varscan2
- ADCY6 | c.2917C>G p.Q973E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV57166522; called by muse, varscan2
- ADRA2A | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54527065; called by muse, mutect2, varscan2
- ALPK2 | c.4652C>G p.A1551G | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV64490787; called by muse, mutect2, varscan2
- ALS2 | c.3656C>T p.T1219I | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372936145, COSV51884833; called by muse, mutect2, varscan2
- AQP9 | c.510G>C p.M170I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54967814; called by muse, mutect2, varscan2
- ASXL2 | c.878C>A p.S293* | Nonsense Mutation (SNP) | VAF 9/102 reads (9%) | catalogued as COSV99710147, COSV99711704; called by muse, mutect2
- ATG2B | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.073); catalogued as COSV100737674; called by muse, mutect2
- ATP13A2 | c.450G>C p.K150N | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV58698555; called by muse, mutect2, varscan2
- BCL9 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as COSV52341779; called by muse, mutect2
- BRINP3 | c.1410C>A p.S470R | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.154); catalogued as COSV66514388, COSV66515243; called by muse, mutect2
- BRWD3 | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV64744742; called by muse, mutect2, varscan2
- CNTRL | c.6731G>A p.R2244Q | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.213); catalogued as rs764424296, COSV53042807; called by muse, mutect2
- CPN1 | c.755A>G p.Q252R | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs748121885, COSV64942006; called by muse, mutect2, varscan2
- CSH1 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100298184; called by muse, mutect2
- CSTB | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.966); catalogued as rs765382240, COSV52366637; called by muse, mutect2, varscan2
- CXorf56 | c.163_165del p.R55del | In Frame Del (DEL) | VAF 17/70 reads (24%) | catalogued as COSV57437783; called by mutect2, pindel, varscan2
- DCC | c.516C>G p.H172Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100498044; called by muse, mutect2
- DCC | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.781); catalogued as rs912869366, COSV71427593, COSV71438411; called by muse, mutect2
- DGKE | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV52349048; called by muse, mutect2, varscan2
- DNAH17 | c.13271G>T p.C4424F | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53143738; called by muse, mutect2
- DNAH7 | c.10895C>T p.A3632V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56754644; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1503G>C p.K501N | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as COSV50051120; called by muse, mutect2, varscan2
- EYA2 | c.1467G>C p.Q489H | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV57939603; called by muse, mutect2
- FAF1 | c.1219A>C p.N407H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.315); catalogued as COSV65636970; called by muse, mutect2, varscan2
- FAM135B | c.3193C>G p.P1065A | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as COSV52709656, COSV52715574, COSV52746385; called by muse, mutect2, varscan2
- FAM184A | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 11/114 reads (10%) | catalogued as COSV58853180; called by muse, mutect2
- FCER1A | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV63666661; called by muse, mutect2
- FPGT | c.1403C>G p.S468C | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV63835444; called by muse, mutect2, varscan2
- GJA5 | c.736G>C p.A246P | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV54783105; called by muse, mutect2
- GLRX2 | c.124G>C p.E42Q (on ENST00000367439 / NM_197962.3; = p.E43Q on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.055); catalogued as COSV100814133, COSV100814215; called by muse, mutect2
- GTF2IRD1 | c.2368G>A p.E790K (on ENST00000265755 / NM_016328.3; = p.E775K on NM_005685.4) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.096); catalogued as COSV56084897; called by muse, mutect2, varscan2
- HEXIM1 | c.309C>G p.F103L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs753721065, COSV60176732, COSV60176918; called by muse, mutect2
- ICAM5 | c.1339G>C p.D447H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV55746345; called by muse, mutect2, varscan2
- IGLV4-3 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs1386507753; called by muse, mutect2
- KCNC1 | c.1122T>G p.N374K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV56392174; called by muse, mutect2, varscan2
- KMT2B | c.5954G>C p.G1985A | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.503); catalogued as COSV55858080; called by muse, varscan2
- KRTAP5-1 | c.789C>A p.C263* | Nonsense Mutation (SNP) | VAF 6/128 reads (5%) | catalogued as COSV101192865, COSV66299029; called by muse, mutect2
- KSR2 | c.2616G>A p.W872* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100194163; called by muse, mutect2, varscan2
- LAS1L | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as COSV56706542; called by mutect2, varscan2
- LILRB5 | c.707G>C p.R236P | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60255251; called by muse, mutect2
- LRIG3 | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as rs767613875, COSV57861418, COSV57862012; called by muse, mutect2
- LRRC14 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV52878069; called by muse, mutect2, varscan2
- LRRCC1 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100835286, COSV100835699; called by muse, mutect2
- MED12L | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56370908; called by muse, mutect2, varscan2
- MREG | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV54372980; called by muse, mutect2
- MYH11 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55543785, COSV55545327; called by muse, mutect2, varscan2
- NLRP2 | c.1870C>G p.Q624E | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT tolerated (0.27); PolyPhen benign (0.116); catalogued as COSV54752905; called by muse, mutect2, varscan2
- NLRP2 | c.2608C>G p.L870V | Missense Mutation (SNP) | VAF 8/250 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54752919; called by muse, mutect2
- NR3C1 | c.561C>A p.D187E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs750705576, COSV51540505; called by muse, mutect2, varscan2
- NUDT21 | c.679A>G p.N227D | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV55859542; called by muse, mutect2, varscan2
- OR2Z1 | c.55A>T p.S19C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV60691823; called by muse, mutect2
- PC | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333294620, COSV58992205; called by muse, mutect2, varscan2
- PDE4DIP | c.3040C>T p.H1014Y | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs782172191, COSV57680782; called by muse, mutect2, varscan2
- PSEN2 | c.516G>C p.L172F | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60915037, COSV60915106; called by muse, mutect2, varscan2
- PTPN12 | c.1723C>A p.Q575K | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV50354581; called by muse, mutect2
- RAF1 | c.248T>C p.M83T | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.21); catalogued as rs753517162, COSV52575591; called by muse, mutect2
- RPGRIP1L | c.550G>C p.D184H | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV50903125; called by muse, mutect2
- RPS26 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV100008878; called by muse, mutect2
- RTCB | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV53277553, COSV99322419; called by muse, mutect2
- SCAF4 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV54590136; called by muse, mutect2
- SETX | c.3833C>T p.P1278L | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56380060; called by muse, mutect2
- SFI1 | c.3484C>T p.H1162Y (on ENST00000400288 / NM_001007467.3; = p.H1131Y on NM_014775.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.354); catalogued as COSV56716254; called by muse, mutect2, varscan2
- SHOX2 | c.878C>T p.S293L (on ENST00000441443 / NM_006884.3; = p.S317L on NM_003030.4) | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV67463412, COSV67463596; called by muse, mutect2, varscan2
- SLC16A6 | c.760C>G p.H254D | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV59176497; called by muse, mutect2, varscan2
- SLC39A6 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); catalogued as COSV52368083; called by muse, mutect2, varscan2
- SOX6 | c.105A>C p.Q35H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.212); catalogued as COSV57039027; called by muse, mutect2
- SOX6 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.017); catalogued as COSV57039053, COSV57049882; called by muse, mutect2
- SPTA1 | c.3849G>C p.E1283D | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV100935634, COSV63749849; called by muse, mutect2
- TENM1 | c.3436C>T p.P1146S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV64426552; called by muse, mutect2, varscan2
- TIMM21 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV50053393; called by muse, mutect2, varscan2
- TRAM1L1 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.894); catalogued as COSV60291387; called by muse, mutect2
- TRIM51 | c.653G>C p.R218T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.04); catalogued as COSV99792124; called by muse, mutect2, varscan2
- TTN | c.58115T>C p.V19372A (on ENST00000591111; = p.V11948A on NM_003319.4) | Missense Mutation (SNP) | VAF 25/136 reads (18%) | PolyPhen possibly damaging (0.716); catalogued as rs1272918380, COSV59917659; called by muse, mutect2, varscan2
- UNC5D | c.2408C>A p.S803Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99771964; called by muse, mutect2
- VAX1 | c.409C>A p.L137I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53327750; called by muse, mutect2, varscan2
- WFS1 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs773280611, COSV56987826; called by muse, mutect2, varscan2
- WNT5B | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60197431, COSV60197517; called by muse, mutect2
- YTHDC2 | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV50737230; called by muse, mutect2, varscan2
- ZFR2 | c.1351G>T p.G451C | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53596802; called by muse, mutect2
- ZNF333 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99468778; called by muse, mutect2
- ZNF569 | c.227G>C p.R76T | Missense Mutation (SNP) | VAF 17/478 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV57593993; called by muse, mutect2
- CAPN15 | c.3043_3045del p.G1015del | In Frame Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- HDGFL1 | c.228C>A p.S76R | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2
- IFT140 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.231); called by muse, mutect2
- N4BP2 | c.1893_1897del p.E631Dfs*2 | Frame Shift Del (DEL) | VAF 13/107 reads (12%) | called by mutect2, pindel, varscan2
- RB1 | c.2568_2575del p.R857Qfs*5 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- C1QTNF1 | c.585C>T p.F195= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs997154592, COSV59260966; called by muse, mutect2, varscan2
- CAP2 | c.402G>A p.S134= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as rs1219145066, COSV57730513; called by muse, mutect2
- CCDC8 | c.516C>T p.R172= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs1249316819, COSV56772484; called by muse, mutect2, varscan2
- DNAH17 | c.3777C>T p.F1259= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs765725696, COSV67750513; called by muse, mutect2, varscan2
- DST | c.11739G>A p.K3913= (on ENST00000361203 / NM_001374722.1; = p.K1501= on NM_015548.5) | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV55001110; called by muse, mutect2, varscan2
- ERG | c.36C>T p.I12= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV101296717, COSV67360624; called by muse, mutect2, varscan2
- EZR | c.459C>T p.I153= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs1295417619, COSV61452819; called by muse, mutect2, varscan2
- IGHV3-23 | c.135A>G p.G45= | Silent (SNP) | VAF 13/327 reads (4%) | catalogued as rs1555467071; called by muse, mutect2
- LMNTD1 | c.534C>T p.L178= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as COSV51445101, COSV51446468; called by muse, mutect2, varscan2
- MAGEB6 | c.210T>A p.T70= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV66871979; called by muse, mutect2, varscan2
- MCTP1 | c.1428G>A p.L476= | Silent (SNP) | VAF 10/123 reads (8%) | catalogued as COSV56506179; called by muse, mutect2
- MFGE8 | c.201G>A p.E67= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV51555405; called by muse, mutect2, varscan2
- MYO18B | c.7077G>A p.P2359= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs370775470; called by muse, mutect2, varscan2
- NNT | c.318T>C p.Y106= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs756010503, COSV52923094; called by muse, mutect2, varscan2
- NUTM2G | c.1071C>T p.H357= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs573525485, COSV63616958; called by muse, mutect2, varscan2
- OR2M3 | c.99C>A p.A33= | Silent (SNP) | VAF 32/260 reads (12%) | catalogued as COSV101513394; called by muse, mutect2, varscan2
- OR4C11 | c.840C>G p.L280= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100155372, COSV56352389; called by muse, mutect2, varscan2
- OTUD7B | c.2190C>T p.F730= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs1553771246, COSV64915394; called by muse, mutect2, varscan2
- OTUD7B | c.1551C>G p.L517= | Silent (SNP) | VAF 45/170 reads (26%) | catalogued as rs782126027, COSV64915400; called by muse, mutect2, varscan2
- PLCB3 | c.1890C>T p.T630= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV54186264; called by muse, mutect2, varscan2
- PTPRR | c.237G>A p.Q79= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV51726245; called by muse, mutect2, varscan2
- SALL1 | c.2793G>A p.P931= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as rs147312225; called by mutect2, varscan2
- SEC23A | c.21C>T p.F7= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV56971607; called by muse, mutect2
- SUCNR1 | c.837G>T p.V279= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as COSV62911917; called by muse, mutect2
- TRPC4 | c.654C>T p.L218= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as COSV100155858, COSV100157525; called by muse, mutect2
- TTN | c.80526C>T p.I26842= (on ENST00000591111; = p.I19418= on NM_003319.4) | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs758811159, COSV59917629, COSV60192320; called by mutect2, varscan2
- UNC5D | c.2409C>A p.S803= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV54774336; called by muse, mutect2, varscan2
- USH1G | c.693C>T p.F231= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV58880882, COSV58881334; called by muse, mutect2, varscan2
- RPS26 | c.-1G>C | 5'UTR (SNP) | VAF 6/32 reads (19%) | catalogued as rs370598918, COSV100008877; called by mutect2, varscan2
- ST8SIA2 | chr15:92472289 G>A | 3'Flank (SNP) | VAF 12/70 reads (17%) | catalogued as rs751058990; called by muse, mutect2, varscan2
